CCDI case PBBRHM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/372cb902-d4d6-4700-8f06-cc2cbadc36f2

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical choroid plexus papilloma: ICD-O-3 morphology code: 9390/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.0 years (1,445 days).

Biospecimens (2 samples)
- Sample 0DGJ65: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGJ7M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
